CCDI case PBBVLK — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/aee05b04-6159-4bfe-85aa-07970213674a

Demographics
Sex at birth: female; Ethnicity: hispanic or latino; Vital status: Alive.

Diagnoses (1)
1. Ependymoma, NOS: ICD-O-3 morphology code: 9391/3; Tissue or organ of origin: Occipital lobe; Age at diagnosis: 12.9 years (4,715 days).

Biospecimens (3 samples)
- Sample 0DII36: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DII3I: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DII45: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
